Somatic mutation profile of tumor specimen TCGA-26-5134-01A (aliquot TCGA-26-5134-01A-01D-1486-08) from TCGA case TCGA-26-5134, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.2 years (27,111 days).
Specimen TCGA-26-5134-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 843c6c22-9eb5-4be6-af9d-aa7c0ba108f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-5134-10A (Blood Derived Normal), aliquot TCGA-26-5134-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b68ee94-38a4-440f-b8d2-f73e5be5e364

The open-access MAF lists 52 somatic variants for this specimen: 44 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 39, Silent 8, Splice Site 2, In Frame Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH1A | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV52925328; called by muse, mutect2, varscan2
- ADRA2B | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs775048172, COSV69788261; called by muse, varscan2
- CD163L1 | c.3029G>T p.C1010F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58018679; called by muse, mutect2, varscan2
- CD33 | c.139A>T p.I47L | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51802595; called by muse, mutect2, varscan2
- CSTF1 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1237637794, COSV53859183, COSV53859422; called by muse, mutect2, varscan2
- CXADR | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53029642; called by muse, mutect2, varscan2
- CYP4Z1 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs145758676, COSV61964103; called by muse, mutect2, varscan2
- DSG3 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs768732577, COSV57124253; called by muse, mutect2, varscan2
- ENAM | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV68536285; called by muse, mutect2, varscan2
- FGA | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165930296, COSV57397534; called by muse, mutect2, varscan2
- GALE | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52526454; called by muse, mutect2, varscan2
- HSPA1L | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65149179; called by muse, mutect2, varscan2
- IGKV1-6 | c.64T>C p.C22R | Missense Mutation (SNP) | VAF 180/378 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs369719427; called by muse, mutect2, varscan2
- ITSN2 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61949398; called by muse, mutect2, varscan2
- KCNU1 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67759518; called by muse, mutect2, varscan2
- KIF15 | c.3445C>G p.Q1149E | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV100393273, COSV58162096; called by muse, mutect2, varscan2
- LRRC43 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60290771; called by muse, mutect2, varscan2
- MECOM | c.2585G>A p.R862K (on ENST00000468789 / NM_001105078.4; = p.R1050K on NM_004991.4) | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV52960378, COSV52967265; called by muse, mutect2, varscan2
- MTHFD1L | c.1806G>A p.A602= | Splice Region (SNP) | VAF 48/133 reads (36%) | catalogued as rs146093887; called by muse, mutect2, varscan2
- NBEA | c.1912G>C p.G638R | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59819274; called by muse, mutect2, varscan2
- NOC3L | c.1799T>C p.V600A | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs779977297, COSV64930042; called by muse, mutect2, varscan2
- OR4K2 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 180/468 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1218850688, COSV53850086; called by muse, mutect2, varscan2
- OR5I1 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56886105, COSV56886672; called by muse, mutect2, varscan2
- OR8D4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 248/548 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58430801; called by muse, mutect2, varscan2
- PCED1A | c.595-1del p.X199_splice | Splice Site (DEL) | VAF 41/106 reads (39%) | catalogued as COSV62313864; called by mutect2, pindel, varscan2
- PCLO | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV61657546; called by muse, mutect2, varscan2
- PCNX1 | c.4978C>T p.R1660* | Nonsense Mutation (SNP) | VAF 114/142 reads (80%) | catalogued as COSV53096786; called by muse, mutect2, varscan2
- PHF12 | c.2587A>G p.T863A | Missense Mutation (SNP) | VAF 162/358 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs374710227; called by muse, mutect2, varscan2
- PIGO | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs781623319, COSV53054092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.11959C>G p.P3987A | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.079); catalogued as COSV64393010; called by muse, mutect2, varscan2
- PRMT9 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV59360172; called by muse, mutect2, varscan2
- PTPN13 | c.6916G>A p.A2306T (on ENST00000411767 / NM_080683.3; = p.A2287T on NM_006264.3) | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57416424; called by muse, mutect2, varscan2
- ROCK2 | c.4136G>A p.S1379N | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV59959692; called by muse, mutect2, varscan2
- SAMD7 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.355); catalogued as COSV59418356, COSV59419517; called by muse, mutect2, varscan2
- SCAF11 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56978029; called by muse, mutect2, varscan2
- SETD2 | c.4839+2T>C p.X1613_splice | Splice Site (SNP) | VAF 119/309 reads (39%) | catalogued as COSV57441524; called by muse, mutect2, varscan2
- SNX16 | c.926A>T p.D309V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV62035593; called by muse, mutect2, varscan2
- TAF1L | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 84/238 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV54268475; called by muse, mutect2, varscan2
- TENT4B | c.2020C>G p.Q674E (on ENST00000561678 / NM_001365323.2; = p.Q659E on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.199); catalogued as COSV62549245; called by muse, mutect2, varscan2
- TYK2 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs1342998501, COSV53388603; called by muse, mutect2, varscan2
- UQCRC1 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52552187, COSV52552499; called by muse, mutect2, varscan2
- VPS51 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as rs1425412470, COSV54209297; called by muse, mutect2, varscan2
- ZNF638 | c.1309C>A p.H437N | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV52490240; called by muse, mutect2, varscan2
- PDGFRA | c.1106_1117del p.K369_E372del | In Frame Del (DEL) | VAF 340/550 reads (62%) | called by mutect2, pindel, varscan2
- EML5 | c.2223C>T p.Y741= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as rs371578525, COSV61347027; called by muse, mutect2, varscan2
- INPP5K | c.27G>C p.P9= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV57441362; called by muse, mutect2, varscan2
- MFSD2A | c.690T>C p.N230= (on ENST00000372809 / NM_001136493.3; = p.N217= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs1166137461, COSV65685940; called by muse, mutect2, varscan2
- MOGAT3 | c.540G>A p.Q180= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV56175121; called by muse, mutect2, varscan2
- PCDHA7 | c.1899G>A p.T633= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as COSV65344998; called by muse, mutect2, varscan2
- VSIG2 | c.786C>T p.C262= | Silent (SNP) | VAF 76/179 reads (42%) | catalogued as rs1184224740, COSV52518836; called by muse, mutect2, varscan2
- WIPF1 | c.1284T>G p.P428= | Silent (SNP) | VAF 81/187 reads (43%) | catalogued as COSV55816245; called by muse, mutect2, varscan2
- ZNF540 | c.1509C>T p.T503= | Silent (SNP) | VAF 91/237 reads (38%) | catalogued as rs1167767539, COSV57109974; called by muse, mutect2, varscan2
